Somatic mutation profile of tumor specimen TCGA-XF-A9SG-01A (aliquot TCGA-XF-A9SG-01A-12D-A42E-08) from TCGA case TCGA-XF-A9SG, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 81.7 years (29,825 days).
Specimen TCGA-XF-A9SG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c4f8033-c7a5-4c9b-b631-2cbccdbf75a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SG-10A (Blood Derived Normal), aliquot TCGA-XF-A9SG-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f00b4c0d-531c-4b75-a3dc-b6e4a85a4775

The open-access MAF lists 205 somatic variants for this specimen: 151 protein-altering or splice-affecting, 48 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 48, Nonsense Mutation 14, Intron 3, Frame Shift Ins 2, Splice Region 1, 5'Flank 1, Splice Site 1, 3'UTR 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLA2G6 | c.1942G>A p.G648R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs794729212, COSV59268450; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.5152G>A p.D1718N (on ENST00000614293; = p.D1688N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.212); catalogued as rs774462817, COSV55798691; called by muse, mutect2, varscan2
- ABCC5 | c.386C>G p.S129* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99657332; called by muse, mutect2, varscan2
- ACAN | c.6367G>C p.D2123H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1257260023, COSV61357552; called by muse, mutect2, varscan2
- AGAP1 | c.2275G>A p.E759K (on ENST00000304032 / NM_001037131.3; = p.E706K on NM_014914.5) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs759890571, COSV58317509; called by mutect2, varscan2
- AGBL5 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.449); catalogued as rs774157105, COSV59935754; called by muse, mutect2, varscan2
- AGTPBP1 | c.2908C>T p.R970C (on ENST00000357081 / NM_001330701.2; = p.R930C on NM_015239.2) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61269504; called by muse, mutect2, varscan2
- AKAP7 | c.1030G>A p.E344K (on ENST00000431975 / NM_016377.4; = p.E77K on NM_004842.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV53833876; called by muse, mutect2, varscan2
- ALDH18A1 | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64662232; called by muse, mutect2, varscan2
- ALOX15B | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.474); catalogued as COSV66479151, COSV66480029; called by muse, mutect2, varscan2
- AMMECR1 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV53316685; called by muse, mutect2, varscan2
- APLNR | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs202019294; called by muse, mutect2, varscan2
- ARFIP2 | c.843C>G p.I281M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54446384; called by muse, mutect2, varscan2
- ARL11 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs1469469563, COSV56291658, COSV99949178; called by muse, mutect2, varscan2
- C12orf40 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV61130175; called by muse, mutect2, varscan2
- C12orf60 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV57451313, COSV57452082; called by muse, mutect2, varscan2
- CACNB3 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as COSV99975054; called by muse, mutect2, varscan2
- CALHM5 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.173); catalogued as COSV62067453; called by muse, mutect2, varscan2
- CAMK1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750784176, COSV56537957; called by muse, varscan2
- CAPRIN1 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs889303170, COSV58218838; called by muse, varscan2
- CAPRIN1 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV58218851; called by muse, mutect2, varscan2
- CAPRIN1 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100404149; called by muse, varscan2
- CASP5 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52827232; called by muse, mutect2, varscan2
- CD1A | c.635C>G p.P212R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV56860768, COSV56863109; called by muse, mutect2, varscan2
- CDKN1A | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV55186863; called by muse, mutect2, varscan2
- CES3 | c.251G>A p.W84* | Nonsense Mutation (SNP) | VAF 33/109 reads (30%) | catalogued as COSV100310014; called by muse, mutect2, varscan2
- CKS2 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58686209; called by muse, mutect2, varscan2
- CLCA2 | c.2163T>G p.I721M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1214435685, COSV65286423; called by muse, mutect2, varscan2
- CNOT1 | c.2552A>G p.Y851C | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55314175; called by muse, mutect2, varscan2
- COG7 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs753113858, COSV56149478; called by muse, mutect2, varscan2
- COL1A2 | c.317G>C p.G106A | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51954682; called by muse, mutect2, varscan2
- COL1A2 | c.3874C>G p.L1292V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV51954695; called by muse, mutect2, varscan2
- COL4A3 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs781635651, CD161094, COSV67413791; called by muse, mutect2, varscan2
- CR2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs772481080, COSV65507582; called by muse, mutect2, varscan2
- CUBN | c.8821G>A p.D2941N | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV64710144; called by muse, mutect2, varscan2
- DAB2 | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1054018308, COSV100298138, COSV57912997, COSV57916154; called by muse, mutect2, varscan2
- DDX4 | c.1081A>G p.K361E | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.345); catalogued as COSV61754085; called by muse, mutect2, varscan2
- DNAH2 | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.465); catalogued as COSV66716117, COSV66717543, COSV66720257; called by muse, mutect2, varscan2
- DNAI3 | c.1979T>C p.M660T | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs943047968, COSV54001186; called by muse, mutect2, varscan2
- DSG2 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.467); catalogued as COSV55197650; called by muse, mutect2, varscan2
- ENAM | c.2971G>A p.G991R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.627); catalogued as COSV68535465; called by muse, mutect2, varscan2
- ENPEP | c.2491C>G p.L831V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54448084; called by muse, mutect2, varscan2
- EPHA5 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1365668708, COSV56635652; called by muse, mutect2, varscan2
- EPHA7 | c.1925G>A p.G642E | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766856886, COSV65178835, COSV65194017; called by muse, mutect2, varscan2
- EPHX1 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55299398; called by muse, mutect2, varscan2
- EQTN | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV66217998; called by muse, mutect2, varscan2
- FAT1 | c.11479C>T p.P3827S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71672680; called by muse, mutect2, varscan2
- FLNB | c.291C>T p.I97= | Splice Region (SNP) | VAF 40/106 reads (38%) | catalogued as COSV55873303, COSV55887697, COSV55888700; called by muse, mutect2, varscan2
- GGNBP2 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as rs756087485; called by muse, mutect2, varscan2
- GGTLC1 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as rs768151671, COSV53846655; called by muse, mutect2, varscan2
- GIMAP2 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226860653, COSV56234722; called by muse, mutect2, varscan2
- GPR176 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100137407; called by muse, mutect2, varscan2
- GRAMD1C | c.507C>G p.I169M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.347); catalogued as COSV63982156; called by muse, mutect2, varscan2
- GTF3C1 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV62239617; called by muse, mutect2, varscan2
- H2BC8 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55126416, COSV55128045, COSV99773107; called by muse, mutect2, varscan2
- HDAC5 | c.2657C>G p.S886C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52242166; called by muse, mutect2, varscan2
- HFE | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as rs139523708, COSV58512689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRNR | c.3242C>G p.S1081C | Missense Mutation (SNP) | VAF 118/494 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs778106352, COSV64255463; called by muse, mutect2, varscan2
- IGLV11-55 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs745996404, COSV66504447; called by muse, mutect2, varscan2
- IGLV3-10 | c.332G>C p.S111T | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.484); catalogued as rs769890657; called by muse, varscan2
- KCNB2 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.124); catalogued as rs1160149602, COSV73049342; called by muse, mutect2, varscan2
- KCNMA1 | c.2344T>G p.S782A (on ENST00000286628 / NM_001161352.2; = p.S724A on NM_002247.4) | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV54234489; called by muse, mutect2
- KIAA0408 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64105542; called by muse, mutect2, varscan2
- KIFBP | c.534T>A p.S178R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV62831349; called by muse, mutect2, varscan2
- KMT2D | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV56470894, COSV99984746; called by muse, mutect2, varscan2
- LIPE | c.2373G>C p.K791N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as COSV54921833; called by muse, varscan2
- LRPPRC | c.284G>C p.R95P | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546209070, COSV53235396, COSV53241262; called by muse, mutect2, varscan2
- LRRC40 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63941662, COSV63941746; called by muse, mutect2, varscan2
- LTN1 | c.1653G>C p.E551D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs370325007; called by muse, mutect2, varscan2
- MAGI2 | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs776118272, COSV62640255; called by muse, mutect2, varscan2
- MAPT | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs773820376, COSV52238204; called by muse, mutect2, varscan2
- MARS2 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56570893, COSV56572225; called by muse, mutect2, varscan2
- MED13L | c.4990G>A p.E1664K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV56117144; called by muse, mutect2, varscan2
- MGAM | c.2713C>T p.L905F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as COSV72073978; called by muse, mutect2, varscan2
- MKNK2 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV51731027; called by muse, mutect2, varscan2
- MMP20 | c.963G>C p.W321C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52774451; called by muse, mutect2
- MMRN1 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV53334953; called by muse, mutect2, varscan2
- MTUS2 | c.2032C>T p.L678F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV70914775; called by muse, varscan2
- MYOM2 | c.2336C>G p.S779* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100038097; called by muse, mutect2, varscan2
- N4BP1 | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV52209975; called by muse, mutect2, varscan2
- NAP1L5 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV52017412, COSV52018351; called by muse, mutect2, varscan2
- NAT10 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57662780; called by muse, mutect2, varscan2
- NAT10 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99140357; called by muse, mutect2, varscan2
- NAT10 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs776480746, COSV57662790; called by muse, varscan2
- NAT10 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV57662798; called by muse, mutect2, varscan2
- NFRKB | c.2297C>T p.S766L (on ENST00000446488 / NM_001143835.2; = p.S791L on NM_006165.3) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.261); catalogued as COSV58756911; called by muse, mutect2, varscan2
- NHP2 | c.309G>T p.L103F | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1317778833, COSV51070852; called by muse, mutect2, varscan2
- NLGN1 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as COSV64326237; called by muse, mutect2, varscan2
- NOS1 | c.2801C>T p.T934I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs1265318198, COSV57608470; called by muse, mutect2, varscan2
- NUP155 | c.4162G>C p.E1388Q (on ENST00000231498 / NM_153485.3; = p.E1329Q on NM_004298.4) | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV51527924; called by muse, mutect2
- NUP210 | c.4514C>T p.S1505L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54403748; called by muse, mutect2
- OGDH | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV56046808, COSV56055554; called by muse, mutect2, varscan2
- OR10G7 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.347); catalogued as COSV57866101; called by muse, mutect2
- OR10J3 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59953839; called by muse, mutect2, varscan2
- OR2V2 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV60314888, COSV60315690; called by muse, mutect2, varscan2
- OR4S1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs61749290, COSV60678844; called by muse, mutect2, varscan2
- OR5V1 | c.8G>C p.R3T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.049); catalogued as rs776585406, COSV65826818, COSV65827748; called by muse, mutect2, varscan2
- PADI4 | c.1301G>A p.C434Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.369); catalogued as rs531738255, COSV100966896; called by muse, mutect2
- PARP4 | c.3502C>T p.L1168F | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV67960948; called by muse, mutect2
- PCDHA1 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.104); catalogued as COSV65373163; called by muse, mutect2, varscan2
- PCDHAC2 | c.1162A>T p.S388C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438894870, COSV53840735; called by muse, mutect2, varscan2
- PDCD4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.095); catalogued as COSV54522127; called by muse, mutect2, varscan2
- PHLDB2 | c.2647G>A p.E883K (on ENST00000393925 / NM_001134439.2; = p.E840K on NM_145753.2) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.404); catalogued as rs759084793, COSV67309066; called by muse, mutect2, varscan2
- PIKFYVE | c.3802C>T p.Q1268* | Nonsense Mutation (SNP) | VAF 165/420 reads (39%) | catalogued as rs1256648178, COSV100011247; called by muse, mutect2, varscan2
- PLEKHA5 | c.1865G>C p.R622T | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.177); catalogued as COSV54696143; called by muse, mutect2, varscan2
- PLEKHA7 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63043786; called by muse, mutect2, varscan2
- PRH2 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as rs374103538; called by muse, mutect2, varscan2
- PTPN14 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs765413797, COSV65281577, COSV65282150; called by muse, mutect2, varscan2
- PTPRZ1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66432414; called by muse, mutect2, varscan2
- RAPGEF2 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV52425790; called by muse, mutect2, varscan2
- RNF185 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201108552; called by muse, mutect2, varscan2
- RRBP1 | c.2282G>A p.R761H (on ENST00000377813 / NM_001365613.2; = p.R328H on NM_004587.3) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773711997, COSV55697208; called by muse, mutect2, varscan2
- RYR2 | c.2680G>A p.V894I | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV63670569; called by muse, mutect2, varscan2
- SACS | c.9043A>T p.I3015F | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV66536351; called by muse, mutect2, varscan2
- SALL1 | c.3905G>A p.S1302N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV51754641; called by muse, mutect2, varscan2
- SART1 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56710477; called by muse, mutect2, varscan2
- SBF2 | c.1574G>T p.C525F | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.862); catalogued as COSV56294102; called by muse, mutect2, varscan2
- SELENOP | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs759244077, COSV72484671; called by muse, mutect2, varscan2
- SENP6 | c.458+1G>T p.X153_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV59189902; called by muse, mutect2, varscan2
- SLC10A2 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as rs1002927427, COSV55357631; called by muse, mutect2, varscan2
- SLC5A7 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50889708; called by muse, mutect2, varscan2
- SMARCA5 | c.1912G>C p.V638L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV51642866; called by muse, mutect2, varscan2
- SMTNL1 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.388); catalogued as COSV101216603, COSV67699281; called by muse, mutect2, varscan2
- SPTBN1 | c.3728C>G p.S1243* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100443196; called by muse, mutect2, varscan2
- ST3GAL5 | c.826G>C p.E276Q (on ENST00000377332; = p.E316Q on NM_003896.4) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV60385243; called by muse, mutect2
- SUPT5H | c.2294A>G p.Y765C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63238669; called by muse, mutect2, varscan2
- SYCP2 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62766716; called by muse, mutect2, varscan2
- SYNE1 | c.346G>A p.D116N (on ENST00000367255 / NM_182961.4; = p.D123N on NM_033071.3) | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54930071; called by muse, mutect2, varscan2
- TEX15 | c.2672G>A p.G891E (on ENST00000256246; = p.G1274E on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1288104036, COSV56343250; called by muse, mutect2, varscan2
- TFPT | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52927163; called by muse, mutect2, varscan2
- THRA | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52841346; called by muse, mutect2, varscan2
- TIGD2 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57647340; called by muse, mutect2, varscan2
- TIMP2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs780171870, COSV53160138; called by muse, mutect2, varscan2
- TLL2 | c.2920G>C p.E974Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV63571297; called by muse, mutect2, varscan2
- TNPO3 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV55279075; called by muse, mutect2, varscan2
- TTN | c.89648C>T p.S29883L (on ENST00000591111; = p.S22459L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | PolyPhen benign (0.074); catalogued as rs796571658, COSV100624043; called by muse, mutect2
- UTRN | c.5420C>T p.A1807V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs777524827, COSV62330062; called by muse, mutect2, varscan2
- VPS13D | c.5173C>T p.L1725F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50624497; called by muse, mutect2, varscan2
- WDR47 | c.1894G>T p.V632L (on ENST00000369962 / NM_001142551.2; = p.V633L on NM_014969.5) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as COSV63057100; called by muse, mutect2, varscan2
- WDR81 | c.4522G>A p.E1508K (on ENST00000409644 / NM_001163809.2; = p.E457K on NM_152348.4) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as rs745403738, COSV100489190, COSV58479431; called by muse, mutect2, varscan2
- XIRP2 | c.6388G>A p.E2130K (on ENST00000628543; = p.E2305K on NM_152381.6) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV54688018; called by muse, mutect2, varscan2
- ZNF219 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV53878840, COSV53884509; called by muse, mutect2, varscan2
- ZNF292 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV60536712, COSV60536825; called by muse, mutect2, varscan2
- ZNF337 | c.2114G>C p.R705T | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as rs1254010243, COSV53320574, COSV99430562; called by muse, mutect2, varscan2
- ZNF347 | c.1774A>G p.T592A | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV61967889; called by muse, mutect2, varscan2
- ZNF624 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs1413160081, COSV60939507; called by muse, mutect2, varscan2
- ZNF786 | c.1727G>C p.R576T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV100302948; called by muse, mutect2
- ASB3 | c.72dup p.V25Sfs*16 | Frame Shift Ins (INS) | VAF 38/125 reads (30%) | called by mutect2, pindel, varscan2
- CEP89 | c.2257_2260del p.V753Pfs*23 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by mutect2, pindel, varscan2
- MYO19 | c.2179G>A p.D727N (on ENST00000614623 / NM_001163735.1; = p.D527N on NM_025109.5) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UGT1A3 | c.262_263dup p.F89Nfs*20 | Frame Shift Ins (INS) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- ABCB6 | c.2262G>A p.T754= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs188495459; called by muse, mutect2, varscan2
- ADRB1 | c.606G>A p.E202= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV65167697; called by muse, mutect2, varscan2
- BBS7 | c.369C>T p.L123= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV52655122; called by muse, mutect2, varscan2
- BRINP2 | c.1077C>T p.S359= | Silent (SNP) | VAF 49/250 reads (20%) | catalogued as COSV64176230; called by muse, mutect2, varscan2
- CHGB | c.861G>A p.R287= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1189481366, COSV66759841; called by muse, mutect2, varscan2
- CIAO3 | c.699G>A p.L233= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs1158910421, COSV99285102; called by muse, mutect2, varscan2
- CNTN6 | c.1974C>T p.Y658= | Silent (SNP) | VAF 14/104 reads (13%) | catalogued as COSV63165189; called by muse, mutect2, varscan2
- CPPED1 | c.894G>A p.L298= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV55496238, COSV55497373; called by muse, mutect2, varscan2
- CYP4F22 | c.645C>G p.V215= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV54107174; called by muse, mutect2, varscan2
- DLG5 | c.4398C>T p.V1466= | Silent (SNP) | VAF 12/170 reads (7%) | catalogued as COSV64947190; called by muse, mutect2
- EPB41L2 | c.1197G>A p.K399= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV61353915; called by muse, mutect2, varscan2
- ESF1 | c.2343G>A p.K781= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs757865963, COSV52519597, COSV52525483; called by muse, mutect2, varscan2
- ESYT2 | c.1770C>T p.F590= (on ENST00000613624; = p.F514= on NM_020728.3) | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV51748689; called by muse, mutect2, varscan2
- F10 | c.159C>T p.L53= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV65021048; called by muse, mutect2, varscan2
- FBN3 | c.2529G>A p.G843= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV54455749; called by muse, mutect2, varscan2
- FGF12 | c.678T>C p.S226= (on ENST00000454309 / NM_021032.5; = p.S164= on NM_004113.6) | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as COSV53156856; called by muse, mutect2, varscan2
- GCNT2 | c.1146G>A p.L382= (on ENST00000379597 / NM_001374747.1; = p.L380= on NM_001491.3) | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs1441369479, COSV53941358, COSV99399380; called by muse, mutect2, varscan2
- GEMIN6 | c.258C>T p.F86= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56140187; called by muse, mutect2, varscan2
- GOT2 | c.363G>A p.L121= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs1373670427, COSV55331089; called by muse, mutect2, varscan2
- HDAC1 | c.129C>G p.L43= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV65190621; called by muse, mutect2, varscan2
- LYST | c.9438G>A p.L3146= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV67704412; called by muse, mutect2, varscan2
- MAP3K1 | c.567G>A p.L189= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs765449441, COSV68122418; called by muse, mutect2, varscan2
- MARVELD2 | c.1311C>T p.I437= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs770148046, COSV57779778, COSV57781074; called by muse, mutect2, varscan2
- MMP20 | c.1212G>A p.Q404= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs762087055, COSV52774434; called by muse, mutect2, varscan2
- MMP25 | c.678C>T p.D226= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs757079699, COSV60678892; called by muse, mutect2, varscan2
- MRPL40 | c.162G>A p.K54= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1333641643, COSV54273145; called by mutect2, varscan2
- MTUS2 | c.1963C>T p.L655= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1458501063, COSV101462323; called by muse, varscan2
- MUSK | c.1077G>C p.L359= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs1238317983, COSV51880075; called by muse, mutect2, varscan2
- NAT10 | c.720G>A p.E240= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs367962262; called by muse, varscan2
- NBPF1 | c.1587C>T p.L529= | Silent (SNP) | VAF 45/1178 reads (4%) | catalogued as rs765048077; called by muse, mutect2
- NFASC | c.1287G>A p.P429= (on ENST00000339876 / NM_001378329.1; = p.P440= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs147657218; called by muse, mutect2
- NT5C1A | c.510C>G p.L170= | Silent (SNP) | VAF 36/51 reads (71%) | catalogued as COSV52493558; called by muse, mutect2, varscan2
- OR5V1 | c.408G>C p.L136= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV65826813; called by muse, mutect2, varscan2
- PAMR1 | c.2121G>A p.K707= (on ENST00000619888 / NM_001001991.3; = p.K724= on NM_015430.4) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV53510552; called by muse, mutect2, varscan2
- PARP8 | c.390C>T p.D130= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV55857401; called by muse, mutect2, varscan2
- PDE3B | c.1881G>A p.K627= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56380944; called by muse, mutect2, varscan2
- PDILT | c.873C>T p.I291= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV56700336; called by muse, mutect2, varscan2
- PHF3 | c.64C>T p.L22= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV50314687; called by muse, mutect2, varscan2
- POLR1A | c.5070C>T p.H1690= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs777899218, COSV99808213; called by muse, mutect2
- PPM1K | c.885C>T p.L295= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV55795348; called by muse, mutect2, varscan2
- PTPRE | c.1542C>T p.I514= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV54547792; called by muse, mutect2, varscan2
- SART1 | c.501G>C p.L167= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV56710465; called by muse, mutect2, varscan2
- SNAPIN | c.318G>A p.L106= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100721986; called by muse, mutect2
- SRSF6 | c.765G>T p.R255= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99719589, COSV99719802; called by muse, mutect2
- TNS1 | c.4854C>T p.I1618= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV50693214; called by muse, mutect2
- TSPAN12 | c.540C>T p.S180= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs759855646, COSV56078899; called by muse, mutect2, varscan2
- UNC50 | c.219G>A p.T73= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV60830988; called by muse, mutect2, varscan2
- ZNFX1 | c.129C>T p.L43= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs756511657, COSV65574270; called by muse, mutect2, varscan2
- ACSM3 | c.639-9C>G | Intron (SNP) | VAF 47/118 reads (40%) | catalogued as COSV55500343, COSV55503059; called by muse, mutect2, varscan2
- APTX | c.-122C>T | 5'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as COSV58927885; called by muse, mutect2, varscan2
- FOXP1 | c.181-17952C>A | Intron (SNP) | VAF 11/54 reads (20%) | catalogued as rs776051503, COSV100562173; called by muse, mutect2, varscan2
- MRAP2 | c.*1G>A | 3'UTR (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100004942; called by muse, mutect2, varscan2
- RSRC1 | chr3:158106011 G>A | 5'Flank (SNP) | VAF 20/57 reads (35%) | catalogued as COSV55825056; called by muse, mutect2, varscan2
- TTN | c.10360+5131G>A | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as COSV59935790; called by muse, mutect2, varscan2
